CPTAC case C3N-08031 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8e624808-f01f-42a7-99b8-ab64de24a29e

Demographics
Sex at birth: female; Race: white; Year of birth: 1983; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 38.7 years (14,122 days); Year of diagnosis: 2021; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: TX; AJCC pathologic N: N3b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 866 days (2.4 years); Progression or recurrence: no; Days to last follow up: 866 days (2.4 years); Tumor focality: Unifocal; Ulceration indicator: Yes.
   Pathology details: Greatest tumor dimension: 4 cm; Lymph node involvement: Positive; Lymph nodes positive: 6; Lymph nodes tested: 25; Lymphatic invasion present: Yes; Margin status: Uninvolved; Vascular invasion present: Yes.
   Immunotherapy (Including Vaccines) — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 406 days (1.1 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 866 days (2.4 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-08031-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 113 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-08031-21: Section location: Lymph node; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3N-08031-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 1 day; Method of sample procurement: Blood Draw.
